Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5432, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5432-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

(A) LOWER JUGULAR LYMPH NODE:

Lymph node, no tumor.

(B) TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY, AND BILATERAL NECK DISSECTION WITH SUBTOTAL THYROIDECTOMY:

SQUAMOUS CARCINOMA GRADE 3 INVOLVING LEFT VOCAL CORD, LEFT VENTRICLE, AND LEFT SUPRAGLOTTIC AREA (THICKNESS OF THE TUMOR 2.0 CM).

Margins of resection free of tumor.

Nodular goiter right thyroid.

Twenty-five right cervical nodes.

Thirty-nine left cervical lymph nodes, no tumor.

Specimen designated "B1 to B13", mucosal margins of resection free of tumor.

GROSS DESCRIPTION

(A) LOWER JUGULAR LYMPH NODE - Two tan lymph nodes (the largest of which measures up to 0.6 cm in greatest dimension).

SECTION CODE: A, two lymph nodes.

(B) TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY AND BILATERAL NECK DISSECTION WITH SUBTOTAL THYROIDECTOMY - A total laryngectomy with bilateral neck dissection with overall measurements of 15.0 x 15.0 x 5.5 cm. The laryngeal component is measuring 9.0 x 6.0 x 3.5 cm. On the left supraglottic area there is a fungating ulcerated and soft mass measuring 3.5 x 3.5 x 2.0 cm. The tumor involves the left vocal cord and supraglottic area with impingement on the midline without involvement of the right glottic area. Tumor extends 2.5 cm in the supraglottic region. No gross involvement of the soft tissue is identified and the mucosa surrounding the tumor appears unremarkable. There is an additional nodule in the left pyriform sinus. There is no connection between this nodule and the main tumor. The nodule is light-tan, slightly raised and measuring 1.5 cm x 1.0 x 0.4 cm.

SECTION CODE: The specimen is submitted as follows: Mucosal margins for frozen section as follows: B, posterior cricoid; B2, inferior left pyriform margin; B3, inferior lateral left pyriform; B4, left lateral pyriform margin; B5, left superolateral pyriform; B6, left superior pyriform; B7 left lateral mollecula; B8, midline and right mollecula; B9, right mollecula; B10, right superior pyriform; B11, right lateral pyriform; B12, right inferior pyriform; B13, right post cricoid. The tumor is submitted entirely from right to left and the block code is B14, right transglottic; B15, right supraglottic mucosa; B16-B31, sequential sections from midline to the left pyriform sinus tumor and

[page 2 of 2]
[REDACTED]

necrosis; B32, B33, from the small nodule in the left pyriform sinus; B34, right thyroid lobe with a small nodule; B35, section of the left colloid nodule; B36 five superior right neck lymph nodes; B37, 3 possible right superior neck lymph nodes; B38, 4 superior right lymph nodes; B39, true right inferior lymph node; B40-B41, 1 right inferior lymph node; B42, 3 right inferior lymph nodes; B43, 4 right inferior lymph nodes; B44, 2 right inferior lymph nodes; B45, 2 left superior lymph nodes; B46, B47, 1 left superior lymph node; B48, 3 left superior lymph nodes; B49, 6 left superior lymph nodes; B50, 4 left inferior lymph nodes; B51, 4 left inferior lymph nodes; B52, 4 left inferior lymph nodes; B53, 4 left inferior lymph nodes; B54, 3 left inferior lymph nodes; B55, 3 left inferior lymph nodes. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA WITH UNDERLYING FIBROADIPOSE TISSUE AND FIBROMUSCULAR TISSUE, NO EVIDENCE OF MALIGNANCY. [REDACTED]

SNOMED CODES

M-80703 T-24455

Source: NCI Genomic Data Commons file 45920db2-5505-4f97-aef3-243f69a04bb1 (TCGA-CV-5432.95F38809-BA7A-43F1-A074-6FDBCF72D1EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).